Somatic mutation profile of tumor specimen TCGA-ET-A39N-01A (aliquot TCGA-ET-A39N-01A-11D-A19J-08) from TCGA case TCGA-ET-A39N, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 35.3 years (12,904 days).
Specimen TCGA-ET-A39N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aba6298f-963f-43ed-a782-24d90c2db62c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A39N-10A (Blood Derived Normal), aliquot TCGA-ET-A39N-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47f5668b-20cc-44d3-82ae-28d4c11f7a74

The open-access MAF lists 5 somatic variants for this specimen: 5 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CSPG4 | c.5719G>A p.V1907M | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.023); catalogued as rs368180303; called by muse, mutect2, varscan2
- LETMD1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 99/165 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.771); catalogued as COSV50399061; called by muse, mutect2, varscan2
- OR5D18 | c.294C>G p.C98W | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs147156620, COSV100450499, COSV61738187; called by muse, mutect2, varscan2
- SYNPO2 | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV61110482; called by muse, mutect2
- UBQLN3 | c.236G>A p.C79Y | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.526); catalogued as COSV61165064; called by muse, mutect2, varscan2
